Somatic mutation profile of tumor specimen BA2984D (aliquot aq-BA2984D) from BEATAML1.0 case 2520, project BEATAML1.0-COHORT (Functional Genomic Landscape of Acute Myeloid Leukemia). Sex at birth: male; Vital status: Dead; Primary diagnosis: Acute myeloid leukemia with mutated NPM1; Tissue or organ of origin: Bone marrow; Age at diagnosis: 81.5 years (29,757 days).
Specimen BA2984D: Sample type: Primary Blood Derived Cancer - Peripheral Blood; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Peripheral Blood NOS; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 00fc25a4-8b1b-4ba2-b162-8a27eb374d0f.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen BA2690D (Solid Tissue Normal), aliquot aq-BA2690D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/0436d4ca-881f-4367-9dcf-34a64f2c4a2b

The open-access MAF lists 9 somatic variants for this specimen: 7 protein-altering or splice-affecting, 2 silent.
By variant classification: Missense Mutation 5, Nonsense Mutation 2, Silent 2.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CLDN20 | c.637C>A p.H213N | Missense Mutation (SNP) | VAF 3/36 reads (8%) | SIFT deleterious (0.05); PolyPhen benign (0); catalogued as rs1051944943; called by muse, mutect2
- SETD2 | c.4945G>A p.G1649R | Missense Mutation (SNP) | VAF 8/154 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV57445233; called by muse, mutect2
- DNM1L | c.1495C>T p.P499S | Missense Mutation (SNP) | VAF 9/218 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); called by muse, mutect2
- KAT6A | c.3928C>T p.Q1310* | Nonsense Mutation (SNP) | VAF 30/125 reads (24%) | called by muse, mutect2, varscan2
- PPP2R5B | c.449A>G p.D150G | Missense Mutation (SNP) | VAF 10/135 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- REV3L | c.4750C>T p.R1584* | Nonsense Mutation (SNP) | VAF 16/210 reads (8%) | called by muse, mutect2
- VAV3 | c.2443G>T p.V815L | Missense Mutation (SNP) | VAF 8/104 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.718); called by muse, mutect2
- C2CD3 | c.2340C>T p.T780= | Silent (SNP) | VAF 20/206 reads (10%) | catalogued as rs1246786728; called by muse, mutect2
- TIGD3 | c.214C>A p.R72= | Silent (SNP) | VAF 4/60 reads (7%) | called by muse, mutect2
